Gene-level copy-number profile of tumor specimen TCGA-QQ-A8VH-01A from TCGA case TCGA-QQ-A8VH, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant peripheral nerve sheath tumor; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 31.8 years (11,599 days).
Specimen TCGA-QQ-A8VH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.3d502bbe-ed09-4e6e-9625-4524226514dc.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-QQ-A8VH-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/66525c60-0995-4655-b9e1-1bfa8755427c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 23; copy number 1: 21,884; copy number 2: 33,299; copy number 3: 2,736; copy number 4: 1,354; copy number 5: 182; copy number 6: 300; copy number 7: 36.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-QQ-A8VH-01A-11D-A37B-01): tumor purity 0.91, ploidy 1.88, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 17 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:181,064,089–181,265,145, 3 genes: LINC00290, AC019235.1, LINC02500.
- chr7:147,080,934–147,097,609, 1 gene: CNTNAP2-AS1.
- chr8:18,527,303–19,084,730, 1 gene (within-gene range 0–2): PSD3.
- chr8:18,774,547–19,259,469, 8 genes (within-gene range 0–2): RPL35P6, AC087821.2, AC087821.1, SNORA62, AC009884.1, AC009884.2, AC100849.1, AC100849.2.
- chr21:14,961,235–15,065,936, 1 gene (within-gene range 0–1): NRIP1.
- chr21:15,050,189–15,052,379, 1 gene: AF127577.6.
- chr21:46,635,595–46,665,124, 2 genes: PRMT2, DSTNP1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 518 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:68,640,798–68,724,048, 2 genes, copy number 5: AC004910.1, RNA5SP231.
- chr8:47,260,878–51,321,118, 48 genes, copy number 6 (within-gene range 4–6): SPIDR, AC024451.2, AC024451.4, AC024451.1, AC024451.3, RNU6-665P, CEBPD, PRKDC, Y_RNA, AC021236.1, MCM4, RNU6-519P, UBE2V2, AC104989.1, IDI1P2, RNU6-295P, RNA5SP531, RPL29P19, AC041040.1, AC026904.1, AC026904.2, AC022915.2, LINC02599, LINC02847, AC022915.1, AC022915.3, EFCAB1, AC100805.1, AC013701.1, SNAI2, AC013701.2, AC044893.2, PPDPFL, AC044893.1, RN7SKP294, RFPL4AP7, AC090155.2, AC090155.1, PSAT1P1, AC113145.1, AC023762.1, SNTG1, AC090539.1, AC090539.2, CYCSP22, AC087272.1, AC090919.1, AC012413.1.
- chr8:51,435,602–51,436,509, 1 gene, copy number 6: BRIX1P1.
- chr8:128,634,199–131,144,948, 29 genes, copy number 5–6 (within-gene range 3–6): CCDC26, AC103833.2, AC103833.1, RN7SKP206, AC011257.1, MIR3686, AC103718.1, MTRF1LP2, GSDMC, AC022973.5, CYRIB, AC022973.2, AC022973.1, AC022973.4, AC022973.3, AC131568.1, RNU7-181P, MIR5194, ASAP1, RNU6-1255P, ASAP1-IT2, AC103725.1, AC009682.1, AC139019.1, AC090987.1, ADCY8, AC103726.1, AC103726.2, AC087341.1.
- chr8:137,105,352–138,497,261, 8 genes, copy number 6: RNU6-144P, ZYXP1, AC105213.1, AC110053.1, AC046195.1, AC046195.2, AC079015.1, FAM135B.
- chr17:17,616,043–22,070,538, 237 genes, copy number 6 (broad region; genes not listed).
- chr19:29,526,499–34,733,837, 117 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr20:51,386,957–56,786,087, 76 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 20,673. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
